Somatic mutation profile of tumor specimen MP2PRT-PARRRR-TMP1-A (aliquot MP2PRT-PARRRR-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARRRR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (452 days).
Specimen MP2PRT-PARRRR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e988d15-4336-41ce-a6a8-c3fb3c150762.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRRR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRRR-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a1e605b-709e-4f24-8e9e-28d4c23d780e

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 179/495 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DOCK4 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- FLG2 | c.3823A>G p.N1275D | Missense Mutation (SNP) | VAF 243/627 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GNB2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 246/602 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FOXK1 | c.1980G>A p.V660= | Silent (SNP) | VAF 299/727 reads (41%) | catalogued as rs1236625747; called by muse, mutect2, varscan2
- HIP1R | c.972G>C p.G324= | Silent (SNP) | VAF 18/619 reads (3%) | catalogued as rs1241691588; called by muse, mutect2
